Gene-level copy-number profile of tumor specimen TCGA-CV-7248-01A from TCGA case TCGA-CV-7248, project TCGA-HNSC (Head and Neck Squamous Cell Carcinoma). Sex at birth: female; Vital status: Dead; Primary diagnosis: Squamous cell carcinoma, NOS; Tissue or organ of origin: Larynx, NOS; AJCC pathologic stage: Stage IVA; Tumor grade: G2; Age at diagnosis: 63.2 years (23,082 days).
Specimen TCGA-CV-7248-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file TCGA-HNSC.eef71588-56cf-4ff2-b2a5-09c28dd42c1d.ascat3.gene_level_copy_number.v36.tsv, workflow ASCAT3 (allele-specific copy number) on an Affymetrix SNP 6.0 array pair, germline comparator TCGA-CV-7248-10A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 810 have no estimate. GDC also holds other gene-level copy-number files for this specimen, not rendered: ASCAT2; ABSOLUTE LiftOver.
https://portal.gdc.cancer.gov/files/aa671adc-b511-406a-8052-7ae45e573a02

Most common (modal) total copy number across autosomal genes: 4 — above the diploid value of 2, consistent with a largely gained or genome-doubled tumor.
Genes by total copy number (all chromosomes): copy number 0: 50; copy number 1: 475; copy number 2: 16,252; copy number 3: 9,802; copy number 4: 29,551; copy number 5: 83; copy number 6: 3,065; copy number 7: 335; copy number 8: 73; copy number 9: 82; copy number 11: 8; copy number 12: 14; copy number 15: 10; copy number 20: 7; copy number 25: 6.
ABSOLUTE estimates for this specimen (TCGA Pan-Cancer Atlas, from the SNP 6.0 array, aliquot TCGA-CV-7248-01A-11D-2010-01): tumor purity 0.39, ploidy 1.71, whole-genome doublings 0.

Homozygous deletions (total copy number 0; autosomes only): 50 genes in 2 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr8:3,700,492–3,700,628, 1 gene: RNA5SP251.
- chr10:43,728,217–45,672,780, 49 genes (within-gene range 0–1): SPRING1P1, UQCRHP3, ELOCP30, LINC02658, LINC00840, HNRNPA3P1, LINC02659, LINC00841, AL139237.1, AL137026.2, AL137026.1, LINC02881, AL137026.3, CXCL12, RPL9P21, AL356157.2, AL356157.3, AL356157.1, TMEM72-AS1, EIF2AP4, AL353801.2, TMEM72, AL353801.1, AL353801.3, RASSF4, DEPP1, ZNF22-AS1, ZNF22, CEP164P1, AL358394.3, DUXAP4, RPS19P7, RSU1P2, CUBNP3, AL358394.2, ANKRD54P1, ANKRD30BP3, MIR3156-1, AL358394.1, AL512324.3, AL512324.6, RNU6-1207P, CUBNP2, OR6D1P, OR13A1, ALOX5, AL731567.1, MARCHF8, ZFAND4.

Amplified relative to the modal value (total copy number ≥ 9, i.e. more than twice the modal value of 4; autosomes only): 127 genes in 9 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr4:67,417,305–67,610,313, 7 genes, copy number 20: AC104806.2, RNU1-63P, RNA5SP527, AC104806.1, CENPC, STAP1, AC096720.2.
- chr6:54,307,859–56,954,649, 24 genes, copy number 11–25: TINAG, TINAG-AS1, CLNS1AP1, RPL10P10, RPSAP44, KRASP1, RNU6-1023P, AL512363.1, FAM83B, AL049555.1, HCRTR2, GFRAL, HMGCLL1, AL590290.1, BMP5, NPM1P36, COL21A1, DHFRP6, AL031779.1, RCC2P7, DST, DST-AS1, RPL17P26, RNU6-626P.
- chr6:63,392,222–63,779,336, 11 genes, copy number 12: AL121949.3, AL121949.2, AL121949.1, EEF1B2P5, PTP4A1, RPL7AP34, AL135905.1, AL135905.2, AL513043.1, RPL9P18, PHF3.
- chr6:63,797,189–63,857,769, 3 genes, copy number 12: AL354719.1, SCAT8, GCNT1P4.
- chr6:170,135,374–170,738,536, 22 genes, copy number 9: AL596442.4, AL596442.3, AL596442.1, AL596442.2, RPL12P23, AL109910.1, AL109910.2, LINC01624, DLL1, FAM120B, AL078605.1, MIR4644, AL008628.1, PSMB1, TBP, PDCD2, AL031259.1, AL672310.1, OR4F7P, WBP1LP8, AL731661.1, AL731684.1.
- chr14:83,017,106–86,989,125, 26 genes, copy number 9: AL359238.1, AL162872.1, RNU7-51P, RNU6ATAC28P, AL161713.1, LINC02305, AL356807.1, MTND4P33, MTND5P35, MTCYBP27, RNU6-976P, AL163642.1, AL163642.2, AL357172.1, AL049775.2, LINC02329, LINC00911, AL049775.1, AL049775.3, FLRT2, LINC02328, LINC02316, AL161753.1, LINC02309, LINC01148, AL358292.1.
- chr14:88,562,970–89,619,149, 15 genes, copy number 9 (within-gene range 7–9): ZC3H14, AL162171.3, EML5, AL121768.1, RNU4-92P, TTC8, Y_RNA, AL137785.1, MPPE1P1, FOXN3, AL138478.1, CAP2P1, AL357093.2, AL357093.1, AL356805.1.
- chr14:89,417,354–89,419,793, 1 gene, copy number 9: FOXN3-AS1.
- chr14:96,392,128–97,217,778, 18 genes, copy number 9 (within-gene range 7–9): AK7, PEBP1P1, RPL23AP10, AL163051.1, PAPOLA, AL137786.1, RN7SKP108, AL137786.2, LINC02299, AL137786.3, VRK1, LINC00618, AL049833.3, AL049833.4, AL049833.2, AL049833.1, LINC02304, AL158800.1.

Autosomal genes at a single copy (total copy number 1): 475. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
